Somatic mutation profile of tumor specimen 0DSP2D from CCDI case PBCHZA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.9 years (6,177 days).
Specimen 0DSP2D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f415e647-e253-4338-b0b0-ecb43e7d96ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSP2I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efcc1118-96b9-433f-bf55-e0be6aed70ad

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 4, Nonsense Mutation 2, 5'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 231/646 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 364/859 reads (42%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 118/349 reads (34%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APLP1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs747466333; called by muse, mutect2, varscan2
- EPB41L4B | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 138/745 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201249269, COSV65796261; called by muse, mutect2, varscan2
- OCSTAMP | c.42C>T p.T14= | Splice Region (SNP) | VAF 149/426 reads (35%) | catalogued as rs367584136; called by muse, mutect2, varscan2
- RTN1 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 257/541 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749408245; called by muse, mutect2, varscan2
- TAOK2 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 147/771 reads (19%) | catalogued as rs1411245776, COSV54234830; called by muse, mutect2, varscan2
- TFDP1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 112/513 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs201938481; called by muse, mutect2, varscan2
- TIE1 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 79/539 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs763301824, COSV65249600; called by muse, mutect2, varscan2
- TOPAZ1 | c.3916G>A p.V1306I | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs1025802771; called by muse, mutect2, varscan2
- TRHR | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 178/636 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.514); catalogued as rs768515704, COSV61234406; called by muse, mutect2, varscan2
- A2M | c.4337T>C p.I1446T | Missense Mutation (SNP) | VAF 196/568 reads (35%) | SIFT tolerated (0.86); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CHST1 | c.1157A>G p.K386R | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIP2 | c.2728C>T p.P910S (on ENST00000619221; = p.P813S on NM_001080423.4) | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRKG2 | c.1414G>A p.V472I | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.026); called by muse, varscan2
- UBTF | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 98/583 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.134); called by muse, mutect2
- VPS13D | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 135/334 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WRN | c.2448G>T p.Q816H | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- AJAP1 | c.324G>A p.A108= | Silent (SNP) | VAF 87/189 reads (46%) | catalogued as rs369334665; called by muse, mutect2, varscan2
- CCDC168 | c.4542G>A p.L1514= | Silent (SNP) | VAF 34/225 reads (15%) | called by muse, varscan2
- FURIN | c.777C>T p.D259= | Silent (SNP) | VAF 138/388 reads (36%) | catalogued as rs771941071; called by muse, mutect2, varscan2
- LAMA5 | c.9426G>A p.P3142= | Silent (SNP) | VAF 95/560 reads (17%) | catalogued as rs144900016; called by muse, mutect2, varscan2
- MEGF9 | c.1767G>T p.G589= | Silent (SNP) | VAF 73/445 reads (16%) | called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- PPM1D | c.309G>A p.V103= | Silent (SNP) | VAF 25/302 reads (8%) | called by muse, mutect2
- BMP1 | c.552-9G>A | Intron (SNP) | VAF 113/248 reads (46%) | called by muse, mutect2, varscan2
- KIF5B | c.-33G>A | 5'UTR (SNP) | VAF 17/100 reads (17%) | catalogued as rs1057249826; called by muse, mutect2, varscan2
- PRSS56 | c.547-20C>T | Intron (SNP) | VAF 86/373 reads (23%) | catalogued as rs1167157300, COSV51321845; called by muse, mutect2, varscan2
- SYNRG | c.78-64T>C | Intron (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- VAV1 | c.1093-28del | Intron (DEL) | VAF 27/87 reads (31%) | catalogued as rs1203804765; called by mutect2, varscan2
